MMRF case MMRF_1216 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c45c71aa-0c04-4e48-82d7-8758465dc415

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Dead; Days to death: 1,345 days (3.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.8 years (26,218 days); ISS stage: II; Days to last known disease status: 1,345 days (3.7 years); Days to last follow up: 1,345 days (3.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 33 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 1,023 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 141 days; Days to treatment end: 1,023 days (2.8 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,024 days (2.8 years); Days to treatment end: 1,108 days (3.0 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,207 days (3.3 years); Days to treatment end: 1,345 days (3.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,345.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 0): M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 185 mg/dL; Immunoglobulin G 43.1 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 4.22 mmol/L; Leukocytes 1.4 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 56 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.05 mmol/L; Albumin 28 g/L; Total Protein 8.7 g/dL; Glucose 5.56 mmol/L.
- Day 85 (ECOG 0): M Protein 0.3 g/dL; Immunoglobulin G 6.88 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 1.41 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 5.02 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 49 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 7.7 mmol/L.
- Day 173 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 6.41 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 1 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 1.7 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 56 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 6.05 mmol/L.
- Day 246: Serum Free Immunoglobulin Light Chain, Kappa 0.951 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 7.87 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.89 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 56 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 8.09 mmol/L.
- Day 341 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 8.14 g/L; Immunoglobulin A 1.25 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 67 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 8.03 mmol/L.
- Day 428 (ECOG 0): Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.44 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.94 mmol/L.
- Day 547 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 9.65 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M 0.93 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.36 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 6.49 mmol/L.
- Day 635 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.929 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.26 mg/dL; Immunoglobulin G 8.93 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 1.03 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 81 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.4 mmol/L; Albumin 52 g/L; Total Protein 6.7 g/dL; Glucose 7.59 mmol/L.
- Day 719 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.966 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.45 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 1.12 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 2.6 ×10⁹/L; Platelets 68 ×10⁹/L; Creatinine 46.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 6.38 mmol/L.
- Day 803 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.754 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 6.7 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.96 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 58 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.26 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 6.55 mmol/L.
- Day 887 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.09 mg/dL; Immunoglobulin G 7.18 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 1.04 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 66 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.32 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 6.93 mmol/L.
- Day 981 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.86 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 1.02 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 7.43 mmol/L.
- Day 1,065 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.64 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 1.68 g/L; Immunoglobulin M 1.31 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 46 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 29 g/L; Total Protein 6.7 g/dL; Glucose 7.76 mmol/L.
- Day 1,165 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.4 mg/dL; Immunoglobulin G 24.7 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.82 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 1.3 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 49 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.3 mmol/L; Albumin 29 g/L; Total Protein 7.5 g/dL; Glucose 6.22 mmol/L.
- Day 1,256 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.976 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.92 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.75 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 1.9 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 53 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Total Protein 7.2 g/dL; Glucose 7.04 mmol/L.

Other clinical attributes
- Day -2: Weight: 68 kg; Height: 158 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1216_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1216_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
